Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GP, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GP-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

Metastatic melanoma. - recurrent primary right forearm -> wide excision recurrence. - mets to (R) axilla. -> (R) ax dissection.

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking (Registrar/ Pathologist:

MACROSCOPIC DESCRIPTION

(Dr

Two specimens received.

1. "RIGHT FOREARM MELANOMA STITCH PROXIMAL ASPECT". A large ellipse of skin, 130 x 27 x 10mm deep. A proximal marking is present at one tip, designated 12 o'clock. 3 o'clock half blue, 9 o'clock half black. There is a pigmented nodule 15 x 10 x 12mm in the subcutis which is well clear of both tips. Representative tissue in two blocks (1A-B). There are four further satellite nodules ranging in size from 3 to 6mm across, with a dark brown cut surface, present around the main nodule within a 60mm distance. The satellite nodules are all clear of both tips. Representative tissue in one block (1C).

2. "RIGHT AXILLARY DISSECTION". One piece of fibrofatty tissue 160 x 120 x 50mm with an overlying unremarkable narrow skin ellipse 90 x 20mm. At one end there is attached skeletal muscle piece 7 x 40 x 20mm. The specimen is dissected from the muscle attached end towards the other end, and the lymph node harvested are embedded in this order. The largest node measures up to 45 x 30 x 30mm with a pigmented cut surface. The skeletal muscle is unremarkable.

- A. Three nodes.
- B. Representative section of one grossly involved node.
- C. Four nodes.
- D. Three nodes.
- E. Four nodes.
- F. Four nodes.
- G. Four nodes.
- H. Four nodes.
- J. One representative section of the largest node.

1CS-0-3
Melanoma, NOS 8720/3
Site: lymph node, Axilla C77.3
lw 6/10/11

MICROSCOPIC REPORT

1. "RIGHT FOREARM MELANOMA STITCH PROXIMAL ASPECT":

In the subcutaneous aspect of a scar (1A, 1B) there are nodular areas of recurrent melanoma to a depth of about 11mm and about 0.6mm from the deep inked tissue margin. There are areas of necrosis in this tumour and in two subcutaneous satellites (1C).

[page 2 of 2]
Requested by:

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

2. "RIGHT AXILLARY DISSECTION":

Twenty-three of the 28 lymph nodes identified show metastatic melanoma, several with extranodal spread.

SUMMARY

Skin right forearm : Recurrent melanoma with subcutaneous satellites.

/

Lymph nodes right axilla : Metastatic melanoma (23/28)

REPORTED BY: Prof.

Source: NCI Genomic Data Commons file 8347113a-4c15-4541-9c24-10ff51d894a3 (TCGA-EE-A2GP.2EDF33EE-2FF5-42B4-A15B-A57E6368C944.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).